FM case AD9679 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/582280af-70b2-4c7e-9cc7-09ef1923a5f3

Male, 66.9 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
